Gene-level copy-number profile of tumor specimen C3N-02300-02 from CPTAC case C3N-02300, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 69.4 years (25,366 days).
Specimen C3N-02300-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c6442f5f-4b09-49ce-bd2c-ab3c6b69c14b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02300-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/10253018-891f-4731-ac43-d3f793f1f9c4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 14,032; copy number 2: 42,431; copy number 3: 678; copy number 4: 709; copy number 5: 503; copy number 6: 29; copy number 7: 5; copy number 8: 11; copy number 11: 3.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:58,597,589–58,597,945, 1 gene (within-gene range 0–1): AC010287.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 551 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:107,902,997–107,904,241, 2 genes, copy number 6: AC009963.2, AC009963.1.
- chr3:172,425,850–198,123,232, 508 genes, copy number 5–7 (broad region; genes not listed).
- chr16:46,469,341–47,701,523, 38 genes, copy number 6–8: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2, GPT2, DNAJA2, AC018845.3, AC018845.1, AC018845.2, NETO2, ITFG1-AS1, RPL23AP72, ITFG1, AC007494.2, AC007494.3, AC007494.1, AC007533.1, Y_RNA, 5S_rRNA, PHKB, RNA5SP425, AC007599.2, AC007599.1, EIF4BP5, NDUFA5P11.
- chr22:18,605,355–18,611,919, 3 genes, copy number 11: AC023490.1, RN7SKP131, RIMBP3.

Autosomal genes at a single copy (total copy number 1): 13,300. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
